Somatic mutation profile of tumor specimen HCM-BROD-0418-C71-01A (aliquot HCM-BROD-0418-C71-01A-11D-A87L-36) from HCMI case HCM-BROD-0418-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.5 years (16,625 days).
Specimen HCM-BROD-0418-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c2f55aa-00cb-416f-8e9c-69c09626923f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0418-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0418-C71-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8b3783-f9a4-419f-bfb7-8bdf900e0556

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Intron 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 175/277 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs1338391423, CM992590; called by muse, mutect2, varscan2
- BRDT | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 86/496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475548899; called by muse, mutect2, varscan2
- CCDC141 | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 37/598 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1409291863; called by muse, mutect2
- CHD9 | c.6952C>T p.P2318S | Missense Mutation (SNP) | VAF 127/598 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs771079651, COSV54616482; called by muse, mutect2
- DACT2 | c.1793T>C p.L598P | Missense Mutation (SNP) | VAF 107/722 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV64693030; called by muse, mutect2, varscan2
- DNAH2 | c.5437G>A p.V1813I | Missense Mutation (SNP) | VAF 200/626 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs754083186, COSV66728727; called by muse, varscan2
- DYSF | c.4072G>A p.V1358M | Missense Mutation (SNP) | VAF 169/669 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs760627822, COSV50553093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-1 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 121/577 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV55119404; called by muse, mutect2, varscan2
- KCNH5 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 136/506 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs200292403; called by muse, mutect2, varscan2
- KRT84 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 204/566 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57771546; called by muse, mutect2, varscan2
- MROH2B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 363/761 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.477); catalogued as rs1461880389; called by muse, mutect2, varscan2
- MSTN | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 109/446 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1315783994, COSV53621476; called by muse, mutect2, varscan2
- MYH2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 197/613 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs139755852; called by muse, mutect2, varscan2
- MYO1B | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 117/357 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747519171; called by muse, mutect2, varscan2
- OR2T2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 160/781 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs200389028, COSV100737564; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 176/664 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- SLC26A6 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 191/594 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1479041553, COSV99375489; called by muse, mutect2, varscan2
- TMEM145 | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 164/524 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs775934464; called by muse, mutect2, varscan2
- TTN | c.41332G>A p.A13778T (on ENST00000591111; = p.A6354T on NM_003319.4) | Missense Mutation (SNP) | VAF 111/417 reads (27%) | PolyPhen possibly damaging (0.725); catalogued as rs761783891; called by muse, mutect2, varscan2
- CLCN1 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 157/903 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYLC1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- DENND4B | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 275/798 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX35 | c.153G>C p.R51S | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENPEP | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRRTM4 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 250/717 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RALA | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA3E | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 131/711 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SULF2 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 143/420 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZAN | c.6034A>G p.S2012G | Missense Mutation (SNP) | VAF 99/577 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5C | c.112_113del p.S38* | Frame Shift Del (DEL) | VAF 130/644 reads (20%) | called by mutect2, pindel, varscan2
- CYP46A1 | c.936G>A p.A312= | Silent (SNP) | VAF 208/616 reads (34%) | catalogued as rs1007746329; called by muse, mutect2, varscan2
- DAB2IP | c.525G>A p.T175= (on ENST00000408936; = p.T147= on NM_032552.3) | Silent (SNP) | VAF 220/654 reads (34%) | catalogued as rs559896738, COSV52257503; called by muse, mutect2, varscan2
- HSPA4 | c.1440C>T p.V480= | Silent (SNP) | VAF 39/655 reads (6%) | called by muse, mutect2
- MYOCD | c.543C>T p.D181= | Silent (SNP) | VAF 163/498 reads (33%) | catalogued as rs368720240, COSV58497356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN3 | c.1662C>T p.N554= | Silent (SNP) | VAF 152/432 reads (35%) | catalogued as rs919588386; called by muse, mutect2, varscan2
- SNAP91 | c.180C>T p.A60= | Silent (SNP) | VAF 157/321 reads (49%) | catalogued as rs372957792; called by muse, mutect2, varscan2
- TMEM132B | c.1047G>A p.S349= | Silent (SNP) | VAF 167/520 reads (32%) | catalogued as rs377055980; called by muse, mutect2, varscan2
- UGT3A1 | c.1363C>T p.L455= | Silent (SNP) | VAF 183/767 reads (24%) | called by muse, mutect2, varscan2
- WBP1 | c.600C>A p.P200= | Silent (SNP) | VAF 23/781 reads (3%) | called by muse, mutect2
- C4orf50 | c.-819G>A | 5'UTR (SNP) | VAF 129/555 reads (23%) | catalogued as rs553787371; called by muse, mutect2, varscan2
- CD72 | c.262+58C>A | Intron (SNP) | VAF 210/626 reads (34%) | called by muse, mutect2, varscan2
- FBRSL1 | c.489+1294G>A | Intron (SNP) | VAF 311/1298 reads (24%) | called by muse, mutect2, varscan2
